Gene-level copy-number profile of tumor specimen TCGA-24-2035-01A from TCGA case TCGA-24-2035, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.3 years (23,855 days).
Specimen TCGA-24-2035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.501f96cc-6600-48c6-bb6f-3bd38b1d4d09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2035-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2f72627-4438-4d08-b058-3016f36b7e66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,361; copy number 2: 38,279; copy number 3: 4,887; copy number 4: 1,725; copy number 5: 567.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2035-01A-01D-0663-01): tumor purity 0.61, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 567 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:87,160,103–87,846,817, 20 genes, copy number 5: KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7, IBSP, MEPE.
- chr8:99,695,957–118,111,826, 230 genes, copy number 5 (broad region; genes not listed).
- chr8:118,282,139–118,400,605, 1 gene, copy number 5: AC023590.1.
- chr8:128,634,199–145,066,685, 316 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
